Gene-level copy-number profile of tumor specimen TCGA-AR-A24V-01A from TCGA case TCGA-AR-A24V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.1 years (19,027 days).
Specimen TCGA-AR-A24V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2623f99f-9e60-476b-b522-50e7fc6fef5a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e80a7dfc-bbed-4513-8046-6c4f4c81b6e1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 771; copy number 2: 4,352; copy number 3: 23,510; copy number 4: 13,927; copy number 5: 8,425; copy number 6: 2,272; copy number 7: 4,570; copy number 8: 1,691; copy number 9: 188; copy number 10: 45; copy number 11: 31; copy number 14: 32; copy number 15: 1; copy number 17: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24V-01A-21D-A166-01): tumor purity 0.52, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,563 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–181,342,213, 2,985 genes, copy number 7 (broad region; genes not listed).
- chr8:36,308,245–41,896,762, 125 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr8:42,537,529–145,066,685, 1,575 genes, copy number 8 (broad region; genes not listed).
- chr11:65,695,552–66,843,516, 80 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 9 (within-gene range 2–9): AP003071.5.
- chr11:69,103,493–70,385,312, 37 genes, copy number 9–14 (within-gene range 2–14): AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2.
- chr11:72,685,069–74,746,114, 73 genes, copy number 9 (broad region; genes not listed).
- chr11:131,981,096–131,984,661, 1 gene, copy number 9: AP000844.1.
- chr12:18,683,169–27,446,625, 138 genes, copy number 7–17 (broad region; genes not listed).
- chr12:27,696,388–27,710,803, 1 gene, copy number 10 (within-gene range 2–10): AC009509.1.
- chr12:27,702,338–30,492,302, 44 genes, copy number 10: HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1.
- chr13:29,864,372–31,846,539, 43 genes, copy number 8: Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1.
- chr13:31,952,580–31,961,946, 2 genes, copy number 8: EEF1DP3, AC002525.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
